RC case RC-B5CS — RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature T- and NK-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/564a830d-afea-4897-9685-b7803ff2f103

Demographics
Sex at birth: male; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Year of birth: 1970; Vital status: Dead; Days to death: 441 days (1.2 years); Year of death: 2015; Cause of death: Cancer Related.

Diagnoses (8)
1. Hepatosplenic T-cell lymphoma (the primary disease): ICD-O-3 morphology code: 9716/3; ICD-10 code: C84; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Blood; Classification of tumor: primary; Age at diagnosis: 44.4 years (16,216 days); Year of diagnosis: 2014; Method of diagnosis: Blood Draw; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): Low-Intermediate Risk; Sites of involvement: Bone marrow / Peripheral blood / Spleen.
   Pathology details: Bone marrow malignant cells: Yes; Timepoint category: Initial Diagnosis.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Etoposide + Ifosfamide; Initial disease status: Initial Diagnosis; Regimen or line of therapy: ICE; Days to treatment start: 42 days; Days to treatment end: 43 days; Number of cycles: 1; Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Timepoint category: First Treatment; Treatment effect indicator: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Etoposide + Prednisone + Vincristine; Initial disease status: Progressive Disease; Regimen or line of therapy: EPOCH; Days to treatment start: 62 days; Days to treatment end: 66 days; Treatment outcome: Stable Disease; Reason treatment ended: Other; Timepoint category: Post Initial Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fimepinostat; Initial disease status: Progressive Disease; Days to treatment start: 88 days; Days to treatment end: 106 days; Number of cycles: 1; Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Clinical trial indicator: Yes; Timepoint category: Post Initial Treatment; Treatment effect indicator: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cytarabine + Dexamethasone + Oxaliplatin; Initial disease status: Progressive Disease; Regimen or line of therapy: DHAX; Days to treatment start: 116 days; Days to treatment end: 117 days; Treatment outcome: Stable Disease; Reason treatment ended: Other; Timepoint category: Post Initial Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pralatrexate; Initial disease status: Progressive Disease; Days to treatment start: 137 days; Days to treatment end: 207 days; Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Timepoint category: Post Initial Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Ibrutinib; Initial disease status: Progressive Disease; Days to treatment start: 221 days; Days to treatment end: 249 days; Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Clinical trial indicator: Yes; Timepoint category: Post Initial Treatment; Treatment effect indicator: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pentostatin; Initial disease status: Progressive Disease; Days to treatment start: 256 days; Days to treatment end: 263 days; Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Timepoint category: Post Initial Treatment; Treatment effect indicator: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Alemtuzumab; Initial disease status: Progressive Disease; Days to treatment start: 270 days; Days to treatment end: 326 days; Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Timepoint category: Post Initial Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Alemtuzumab + Gemcitabine; Initial disease status: Progressive Disease; Days to treatment start: 328 days; Days to treatment end: 355 days; Treatment outcome: Progressive Disease; Reason treatment ended: Disease Progression; Timepoint category: Post Initial Treatment; Treatment effect indicator: No.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide + Gemcitabine; Initial disease status: Progressive Disease; Days to treatment start: 358 days; Days to treatment end: 365 days (1.0 years); Treatment outcome: Stable Disease; Reason treatment ended: Other; Timepoint category: Post Initial Treatment.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cytarabine; Initial disease status: Progressive Disease; Days to treatment start: 376 days (1.0 years); Days to treatment end: 412 days (1.1 years); Treatment outcome: Partial Response; Reason treatment ended: Other; Timepoint category: Post Initial Treatment; Treatment effect indicator: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease; Timepoint category: Postoperative.
   Recorded as not given: Organ Transplantation; Stem Cell Transplantation, Allogeneic; Stem Cell Transplantation, Autologous; Stem Cell Transplantation, NOS.
2. Progression (histology not recorded by GDC). Age at diagnosis: 44.6 years (16,273 days); Days to diagnosis: 57 days.
3. Progression (histology not recorded by GDC). Age at diagnosis: 44.7 years (16,332 days); Days to diagnosis: 116 days.
4. Progression (histology not recorded by GDC). Age at diagnosis: 45.0 years (16,424 days); Days to diagnosis: 208 days.
5. Progression (histology not recorded by GDC). Age at diagnosis: 45.1 years (16,465 days); Days to diagnosis: 249 days.
6. Progression (histology not recorded by GDC). Age at diagnosis: 45.1 years (16,483 days); Days to diagnosis: 267 days.
7. Progression (histology not recorded by GDC). Age at diagnosis: 45.3 years (16,542 days); Days to diagnosis: 326 days.
8. Progression (histology not recorded by GDC). Age at diagnosis: 45.4 years (16,574 days); Days to diagnosis: 358 days.

Follow-up (11 entries)
- Day 0 (initial diagnosis): Karnofsky performance status: 90.
- Day 57 (progression): Progression or recurrence: Yes; Days to progression: 57 days.
- Day 116 (progression): Progression or recurrence: Yes; Days to progression: 116 days.
- Day 208 (progression): Progression or recurrence: Yes; Days to progression: 208 days.
- Day 249 (progression): Progression or recurrence: Yes; Days to progression: 249 days.
- Day 267 (progression): Progression or recurrence: Yes; Days to progression: 267 days.
- Days to follow up: 277 days; Disease response: Partial Response.
- Day 326 (progression): Progression or recurrence: Yes; Days to progression: 326 days.
- Day 358 (progression): Progression or recurrence: Yes; Days to progression: 358 days.
- Days to follow up: 379 days (1.0 years); Disease response: Partial Response.
- Day 441 (end of treatment course 1): Imaging type: PET; Imaging result: Positive.

Molecular and laboratory tests
- Lactate Dehydrogenase 220 U/L [Blood test normal range upper: 250].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 71.4 kg; Height: 160 cm; BMI: 27.9.
- Timepoint category: Prior to Diagnosis; Comorbidities: Evan's Syndrome.
- Timepoint category: Prior to Diagnosis; Risk factors: Hematologic Disorder, NOS.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample RC-B5CS-NB1-A: Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen.
- Sample RC-B5CS-TBP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
  Slide RC-B5CS-TBP1-A-1-0-CS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 60; Percent necrosis: 40; Percent stromal cells: 0; Percent lymphocyte infiltration: 90; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 0.
